Somatic mutation profile of tumor specimen TCGA-S9-A6U0-01A (aliquot TCGA-S9-A6U0-01A-12D-A32B-08) from TCGA case TCGA-S9-A6U0, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.2 years (16,890 days).
Specimen TCGA-S9-A6U0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1d07191-4ac2-40a7-946f-b147377e01a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6U0-10A (Blood Derived Normal), aliquot TCGA-S9-A6U0-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19cea6e9-f383-4f36-828f-b25e928f6372

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 8, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs587776932, CM126694, COSV55930478, COSV55944375; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.2255T>A p.L752H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV99282274; called by muse, mutect2, varscan2
- CCSER1 | c.1291A>G p.T431A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100391864; called by muse, mutect2, varscan2
- COL28A1 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1199369584, COSV101258605; called by muse, mutect2, varscan2
- COX10 | c.739G>C p.G247R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99886508; called by muse, mutect2, varscan2
- CUL2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101039152; called by muse, mutect2, varscan2
- DGKA | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs751007578, COSV59383984; called by muse, mutect2, varscan2
- FBN2 | c.5597A>T p.D1866V | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); catalogued as COSV99327550; called by muse, mutect2
- FRAS1 | c.9824G>T p.C3275F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352178; called by muse, mutect2
- KAT6A | c.4461G>T p.Q1487H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.078); catalogued as rs773054740, COSV99705142; called by muse, mutect2, varscan2
- KIAA1549L | c.344C>T p.A115V (on ENST00000321505; = p.A412V on NM_012194.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs758732695, COSV99683531; called by muse, mutect2, varscan2
- LRP10 | c.1897A>G p.T633A | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100612383; called by muse, mutect2, varscan2
- MMP10 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1435227921, COSV99666562; called by muse, mutect2, varscan2
- MYH13 | c.5354G>A p.R1785Q | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs370257882; called by muse, mutect2, varscan2
- MYH13 | c.4090G>A p.A1364T | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV52838723, COSV99354085; called by muse, mutect2, varscan2
- NLE1 | c.701C>A p.T234N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100680974; called by muse, mutect2, varscan2
- NLE1 | c.700A>T p.T234S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100680976; called by muse, mutect2, varscan2
- NR1H3 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs747980109, COSV68008502, COSV68008780; called by muse, mutect2, varscan2
- PCDHA2 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs1554119831, COSV100973878; called by muse, mutect2, varscan2
- PCSK2 | c.1704G>A p.W568* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV52743453; called by muse, mutect2, varscan2
- PGLYRP4 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs200715095, COSV62835998; called by muse, mutect2, varscan2
- PTEN | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV64293130, COSV64294624; called by muse, varscan2
- RYR2 | c.12842C>T p.T4281M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201829896, COSV63685028; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLCO4C1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV60519337; called by muse, mutect2, varscan2
- SORCS3 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769758204, COSV100865131; called by muse, mutect2, varscan2
- SPG11 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV99968695; called by muse, mutect2, varscan2
- SPTA1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs759192785, COSV63748349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVEP1 | c.10264G>A p.V3422I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as rs770700294, COSV99929044; called by muse, mutect2, varscan2
- TEX9 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100771475, COSV61876929; called by muse, mutect2, varscan2
- TXNDC2 | c.1093G>A p.E365K (on ENST00000306084 / NM_001098529.2; = p.E298K on NM_032243.6) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.291); catalogued as COSV100046169, COSV100046659; called by muse, mutect2, varscan2
- ZCCHC12 | c.1069A>G p.K357E | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100038521; called by muse, mutect2
- DCAF12L2 | c.696C>A p.A232= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100758618; called by muse, mutect2, varscan2
- DNAH11 | c.3111C>T p.H1037= | Silent (SNP) | VAF 37/216 reads (17%) | catalogued as rs762093164, COSV100179300; called by muse, mutect2, varscan2
- GPIHBP1 | c.483C>T p.S161= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs370155321; called by mutect2, varscan2
- KLF5 | c.1230C>T p.C410= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as rs767950381, COSV66613447; called by muse, mutect2, varscan2
- SULT1B1 | c.75A>G p.A25= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV100150279; called by muse, mutect2, varscan2
- TP63 | c.1095G>A p.S365= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs748609799, COSV53219679; called by muse, mutect2, varscan2
- WDR93 | c.411G>A p.A137= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs377345020; called by muse, mutect2, varscan2
- ZDBF2 | c.363T>A p.P121= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100984914; called by muse, mutect2, varscan2
- SSX6P | n.104G>A | RNA (SNP) | VAF 70/177 reads (40%) | catalogued as rs782309584; called by muse, mutect2, varscan2
